Somatic mutation profile of tumor specimen BA2499D (aliquot aq-BA2499D) from BEATAML1.0 case 2003, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.5 years (26,098 days).
Specimen BA2499D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11203698-a607-457d-920c-653b4702e4d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2382D (Solid Tissue Normal), aliquot aq-BA2382D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd4c54fe-8885-47ca-a815-9b93a4d50d51

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 2, 3'UTR 2, Frame Shift Ins 2, Nonsense Mutation 2, Intron 1, 5'UTR 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>T p.D835Y | Missense Mutation (SNP) | VAF 78/184 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RUNX1 | c.877C>T p.R293* (on ENST00000344691 / NM_001001890.3; = p.R320* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 137/289 reads (47%) | catalogued as rs1569008655, CM086912, COSV55867803; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- B3GNT4 | c.390C>A p.H130Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV57337072; called by muse, mutect2
- OR2C1 | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs1378989165; called by muse, mutect2
- OR2Z1 | c.223A>G p.M75V | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs782139943; called by muse, mutect2, varscan2
- PRAMEF1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.327); catalogued as rs1413162210; called by muse, mutect2, varscan2
- SH3TC1 | c.236T>A p.V79D | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.022); catalogued as COSV99795455; called by muse, varscan2
- SIGIRR | c.667C>G p.R223G | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1469221049; called by mutect2, varscan2
- ST6GALNAC5 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | PolyPhen possibly damaging (0.466); catalogued as rs763562311, COSV59563661; called by muse, varscan2
- TPCN1 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.396); catalogued as rs570734136; called by muse, varscan2
- TTLL9 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs376433493; called by muse, varscan2
- USP9X | c.4985A>G p.Y1662C | Missense Mutation (SNP) | VAF 46/49 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs960494566; called by muse, mutect2, varscan2
- ZRSR2 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 51/54 reads (94%) | catalogued as rs775221448, COSV57063728; called by muse, mutect2, varscan2
- AKAP11 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 88/188 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- EIF3G | c.597G>T p.E199D | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.115); called by muse, mutect2
- EZH2 | c.1104dup p.T369Hfs*3 (on ENST00000460911 / NM_001203247.2; = p.T374Hfs*3 on NM_004456.5) | Frame Shift Ins (INS) | VAF 82/98 reads (84%) | called by mutect2, varscan2
- HIGD2A | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); called by muse, mutect2
- PLXNA1 | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMC3 | c.130+1G>A p.X44_splice | Splice Site (SNP) | VAF 70/183 reads (38%) | called by muse, mutect2, varscan2
- STAG2 | c.2244_2247dup p.E750Nfs*2 | Frame Shift Ins (INS) | VAF 33/37 reads (89%) | called by mutect2, pindel, varscan2
- THOC2 | c.2389G>A p.V797M | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT tolerated (0.1); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ADAMTS2 | c.597G>A p.A199= | Silent (SNP) | VAF 105/236 reads (44%) | catalogued as rs758074163, COSV99203075; called by muse, mutect2, varscan2
- SLC9A7 | c.1851T>C p.G617= | Silent (SNP) | VAF 22/24 reads (92%) | called by muse, varscan2
- AC116366.2 | c.-383C>A | 5'UTR (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- ADGRL1 | c.*12G>T | 3'UTR (SNP) | VAF 4/53 reads (8%) | catalogued as rs1315812942; called by muse, mutect2
- MFSD4B | c.*742T>C | 3'UTR (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- MT1A | chr16:56635813 T>A | 5'Flank (SNP) | VAF 65/142 reads (46%) | called by muse, mutect2, varscan2
- SLC10A7 | c.183+1941G>A | Intron (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
